Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4UQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4UQ-01A (Primary Tumor).

[page 1 of 5]
Head & Neck
Head And Neck

Primary type:
Additional Copy to:

Clinical Diagnosis & History:

Metastatic papillary thyroid carcinoma.

Specimens Submitted:

- 1: Right neck level 5A lymph nodes
- 2: Right neck level 5-B lymph nodes
- 3: Right neck level 4 lymph nodes
- 4: Right neck levels 2-A and level 3 lymph nodes
- 5: Total thyroidectomy
- 6: Right level 2-B lymph nodes
- 7: Right paratracheal
- 8: Left paratracheal

DIAGNOSIS:

1. Right neck level 5A lymph nodes; excision:
- Benign fibroadipose tissue and skeletal muscle
- No lymph nodes identified in the entirely submitted specimen

2. Right neck level 5-B lymph nodes:

Part # 2

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 10
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 1.0cm.
Size of the largest metastatic focus : 1.0 cm.
Extranodal extension is not identified

ICD-0-3

carcinoma, papillary, diffuse sclerosing
8350/3

Site: thyroid, NOS 673.9

hw
10/27/12

3. Right neck level 4 lymph nodes:

Part # 3

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 8
Number of lymph nodes with metastatic disease: 0

4. Right neck levels 2-A and level 3 lymph nodes:

Part # 4

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 20
Number of lymph nodes with metastatic disease: 5
Size of the largest lymph node involved by tumor: 1.7cm.
Size of the largest metastatic focus : 1.7 cm.

[page 2 of 5]
Extranodal extension is identified

5. Total thyroidectomy:

Part # 5

Tumor Type:

Papillary carcinoma, diffuse sclerosing variant

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Squamous metaplasia

Tumor Location:

Both lobes and isthmus

Tumor Size:

The dominant nodule in the right lobe measures 1.5 cm in greatest dimension

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Present

Extrathyroid Extension:

Invades: Perithyroidal adipose tissue

Surgical Margins:

Free of tumor

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

Lymph Nodes:

Metastatic papillary thyroid carcinoma in four of four lymph nodes (4/4). The largest metastatic node is 0.4 cm in greatest dimension and is completely replaced by tumor. Extra-nodal extension is present.

Comment: Although this rare variant of papillary carcinoma is found mainly in young adults and children, it has been reported in the older population (more than 45 years old). See reference.

Reference: Lam AK. Ann. Surg. Oncol. 2006 Feb;13(2):176-81.

6. Right level 2-B lymph nodes:

Part # 6

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 13

Number of lymph nodes with metastatic disease: 0

Benign salivary gland tissue

7. Right paratracheal:

Part # 7

Lymph Node Dissection:

[page 3 of 5]
Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 8
Number of lymph nodes with metastatic disease: 7
Size of the largest lymph node involved by tumor: 1.1cm.
Size of the largest metastatic focus : 1.1 cm.
Extranodal extension is identified

Microscopic foci of papillary thyroid carcinoma present in adipose tissue. Benign unremarkable parathyroid tissue is identified.

8. Left paratracheal:

Part # 8

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 3
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 1.1cm.
Size of the largest metastatic focus : 1.1 cm.
Extranodal extension is not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain
TTF-1
THYROG
CD31
CD34
D2-40
IMM RECUT
NEG CONT

Comment

Gross Description:

1. The specimen is received fresh, labeled "right neck, level 5A lymph nodes", and consists of possible multiple pink tan firm lymph nodes ranging from 0.2 to 0.8 cm in greatest dimension. The specimen is entirely submitted

Summary of sections:

LN - lymph nodes

2. The specimen is received fresh, labeled "right neck, level 5-B lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.0 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

3. The specimen is received fresh, labeled "right neck, level 4 lymph nodes", and consists of multiple possible pink tan firm lymph nodes ranging from 0.2 to 0.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

[page 4 of 5]
SLN - one serially sectioned lymph node
LN - lymph nodes

4. The specimen is received fresh, labeled "right neck level 2A lymph nodes and level 3", and consists of a 5.0 x 4.2 x 0.3 cm irregular fibrofatty soft tissue fragment to include a portion of skeletal muscle measuring 5.2 x 2.0 x 0.4 cm and multiple pink tan fatty lymph nodes ranging from 0.3 cm up to 1.7 cm in greatest dimension. The largest two lymph nodes have a grossly positive cut surface, and halves of them are submitted for TPS; the remaining halves and all additional identified lymph nodes are entirely submitted.

Summary of sections:

GPL1 - grossly positive lymph node (half for TPS)
GPL2 - grossly positive lymph node (half for TPS)
BLN - bisected lymph nodes
LN - lymph nodes
M - skeletal muscle
U - undesignated

5. The specimen is received fresh, labeled "total thyroidectomy, stitch marks left superior pole", and consists of a thyroid weighing 16.0 g. The right lobe measures 4.4 x 4 x 1.2 cm, the left lobe measures 5 x 2.6 x 1.4 cm and the isthmus measures 2.5 x 1 x 0.8 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, the anterior is inked blue, and the anterior surface of the isthmus is inked green. Sectioning reveals two nodules. The first nodule is located in the superior portion of the right lobe, measuring 1.5 x 0.5 x 0.3 cm. It has a tan-white firm cut surface and the nodule is not encapsulated. The second nodule is located in the mid portion of the right lobe, measures 0.9 x 0.5 x 0.4 cm, displays tan brown firm cut surfaces, and is not encapsulated. Sections through the remaining tissue reveal a diffuse tan homogeneous cut surface. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

RN1 - right superior lobe nodule, entirely submitted
RN2 - right mid lobe nodule, entirely submitted
RL - right lobe
LL - left lobe
IS - isthmus

6. The specimen is received fresh, labeled "right neck, level 2B lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 0.8 cm in greatest dimension. The specimen is entirely submitted

Summary of sections:

LN - lymph nodes

7. The specimen is received fresh, labeled "right paratracheal", and consists of a 3.2 x 2.2 x 0.3 cm irregular fibrofatty soft tissue fragment to include multiple pink tan fatty lymph nodes ranging from 0.3 cm up to 1.1 cm in greatest dimension. The largest has a grossly positive cut surface, and a half is submitted for TPS; the remaining half and all additional identified lymph nodes are entirely submitted.

Summary of sections:

GPL - grossly positive lymph node (half for TPS)
BLN - bisected lymph node
LN - lymph nodes
U - undesignated

8. The specimen is received fresh, labeled "left para-tracheal lymph nodes", and consists of multiple possible pink tan firm lymph nodes ranging from 0.2 to 1.1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

[page 5 of 5]
BLN - bisected lymph node

Summary of Sections:

Part 1: Right neck level 5A lymph nodes

Block	Sect. Site	PCs
3	LN	3

Part 2: Right neck level 5-B lymph nodes

Block	Sect. Site	PCs
5	LN	5

Part 3: Right neck level 4 lymph nodes

Block	Sect. Site	PCs
2	LN	2
2	SLN	2

Part 4: Right neck levels 2-A and level 3 lymph nodes

Block	Sect. Site	PCs
3	BLN	3
1	GPL1	1
1	GPL2	1
3	LN	3
1	M	1
2	U	2

Part 5: Total thyroidectomy

Block	Sect. Site	PCs
4	IS	5
10	LL	10
10	RL	10
1	RN1	1
3	RN2	3

Part 6: Right level 2-B lymph nodes

Block	Sect. Site	PCs
3	LN	3

Part 7: Right paratracheal

Block	Sect. Site	PCs
1	BLN2	1
1	GPL	1
2	LN	2
1	U	1

Part 8: Left paratracheal

Block	Sect. Site	PCs
1	BLN	1
2	LN	2

Source: NCI Genomic Data Commons file a7e5da1a-8293-4443-9e4b-d271459df372 (TCGA-DJ-A4UQ.66B80420-74AB-4AE4-B198-DB616D0484A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).